Somatic mutation profile of tumor specimen TCGA-EI-6883-01A (aliquot TCGA-EI-6883-01A-31D-1924-10) from TCGA case TCGA-EI-6883, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 63.7 years (23,268 days).
Specimen TCGA-EI-6883-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea669861-c5e6-49e7-a3dc-452074c2c175.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EI-6883-10A (Blood Derived Normal), aliquot TCGA-EI-6883-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a55e9a2c-44e6-4c9b-b337-b84c5a961e6c

The open-access MAF lists 97 somatic variants for this specimen: 81 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 15, Nonsense Mutation 6, Frame Shift Del 4, In Frame Del 2, Frame Shift Ins 1, Splice Region 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 87/175 reads (50%) | hotspot (GDC flag); catalogued as rs587781392, CM920027, COSV57321978; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4132C>T p.Q1378* | Nonsense Mutation (SNP) | VAF 31/92 reads (34%) | hotspot (GDC flag); catalogued as rs121913329, CD1110399, CM095537, COSV57322261; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SLC2A1 | c.967G>A p.V323M | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs749426767, COSV65288318; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 34/53 reads (64%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS20 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV67137822; called by muse, mutect2, varscan2
- ADCYAP1 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 48/70 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52486140; called by muse, mutect2, varscan2
- ADGRB1 | c.4619C>T p.T1540M | Missense Mutation (SNP) | VAF 38/199 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as rs773201018, COSV60102718; called by muse, mutect2, varscan2
- AKAP3 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as COSV57419996; called by muse, mutect2, varscan2
- ARPC4 | c.421G>T p.E141* | Nonsense Mutation (SNP) | VAF 47/106 reads (44%) | catalogued as COSV55029541; called by muse, mutect2, varscan2
- ASTN1 | c.3673C>A p.L1225I | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs777653388, COSV62504893; called by muse, mutect2, varscan2
- ATP8B2 | c.2521G>T p.V841L (on ENST00000672630; = p.V808L on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV59248479; called by muse, mutect2, varscan2
- ATR | c.7904A>C p.Q2635P | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53817258; called by muse, mutect2, varscan2
- B4GALNT3 | c.2614C>G p.H872D | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV56757300, COSV56758523; called by muse, mutect2, varscan2
- BPIFB2 | c.82C>T p.R28* | Nonsense Mutation (SNP) | VAF 86/132 reads (65%) | catalogued as rs143361589; called by muse, mutect2
- CACNA1F | c.1783C>T p.R595C | Missense Mutation (SNP) | VAF 57/66 reads (86%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs928731868, COSV59906668; called by muse, mutect2, varscan2
- CAPRIN2 | c.3008A>C p.K1003T | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51835087; called by muse, mutect2, varscan2
- CDH8 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 31/43 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as rs780440408, COSV54847698; called by muse, mutect2, varscan2
- CNTNAP1 | c.2515C>T p.R839W | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs757375034, COSV52853886; called by muse, mutect2, varscan2
- CSPG5 | c.1355C>T p.T452M | Missense Mutation (SNP) | VAF 61/156 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201603317, COSV53133188; called by muse, mutect2, varscan2
- DAG1 | c.1111C>T p.R371W | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs62261248, COSV58186836; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCAF4L2 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 89/135 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV60478562; called by muse, mutect2, varscan2
- DIDO1 | c.5440C>T p.Q1814* | Nonsense Mutation (SNP) | VAF 17/103 reads (17%) | catalogued as COSV56632972; called by muse, mutect2, varscan2
- DNAJC24 | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.134); catalogued as COSV71938862; called by muse, mutect2, varscan2
- EIF4G2 | c.1285T>C p.F429L | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.54); PolyPhen benign (0.259); catalogued as COSV60598930; called by muse, mutect2, varscan2
- ERC2 | c.1481C>T p.A494V | Missense Mutation (SNP) | VAF 73/245 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as rs200558529, COSV55602213; called by muse, mutect2, varscan2
- FAT3 | c.4529G>A p.R1510Q | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.975); catalogued as rs768777673, COSV53165255; called by muse, mutect2, varscan2
- GABRG1 | c.191T>C p.I64T | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as COSV54960870; called by muse, mutect2, varscan2
- GALP | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 34/45 reads (76%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.723); catalogued as rs781105517, COSV61999787; called by muse, mutect2, varscan2
- GPATCH2 | c.969A>C p.E323D | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.118); catalogued as COSV65128430; called by muse, mutect2, varscan2
- HAP1 | c.1801G>A p.E601K (on ENST00000310778 / NM_001367460.1; = p.E549K on NM_177977.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV57880535; called by muse, mutect2, varscan2
- HRNR | c.5997G>T p.Q1999H | Missense Mutation (SNP) | VAF 50/353 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100912661; called by muse, varscan2
- JPH3 | c.2128T>A p.S710T | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV52473239; called by muse, mutect2, varscan2
- KCNA5 | c.1226G>A p.R409H | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1239077980, COSV52908237; called by muse, mutect2, varscan2
- KCNS2 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); catalogued as COSV54639664; called by muse, mutect2, varscan2
- LRFN4 | c.1445G>A p.G482E | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.139); catalogued as rs780659355, COSV100540568; called by muse, mutect2, varscan2
- MYO3A | c.3085G>A p.D1029N | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as rs56403976, COSV56324596; called by muse, mutect2, varscan2
- NEK3 | c.920G>A p.S307N | Missense Mutation (SNP) | VAF 34/37 reads (92%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV51618908; called by muse, mutect2, varscan2
- NOG | c.468del p.V157Cfs*17 | Frame Shift Del (DEL) | VAF 28/87 reads (32%) | catalogued as COSV60446737; called by mutect2, pindel, varscan2
- NTN1 | c.1375C>A p.P459T | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.052); catalogued as rs376278603; called by muse, mutect2, varscan2
- NTSR1 | c.973A>G p.M325V | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.389); catalogued as rs766656202, COSV65139479; called by muse, mutect2, varscan2
- OR52N2 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 93/226 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as rs150750582; called by muse, mutect2, varscan2
- PARD6A | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99537261; called by muse, mutect2, varscan2
- PCDH18 | c.2378G>A p.R793Q | Missense Mutation (SNP) | VAF 70/187 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.478); catalogued as rs767731660, COSV61268085; called by muse, mutect2, varscan2
- PCDHB2 | c.1529C>T p.A510V | Missense Mutation (SNP) | VAF 61/130 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.379); catalogued as COSV50620512; called by muse, mutect2, varscan2
- PCDHB5 | c.703A>G p.N235D | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as COSV50667008; called by muse, mutect2, varscan2
- PCDHB8 | c.1000G>A p.V334I | Missense Mutation (SNP) | VAF 68/543 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.05); catalogued as rs782003552, COSV50754292; called by muse, mutect2, varscan2
- PNLDC1 | c.646C>G p.L216V | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV51707713; called by muse, mutect2, varscan2
- POLN | c.2047G>A p.A683T | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as rs570588303, COSV67027312; called by muse, mutect2, varscan2
- PRL | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 43/64 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs201458155, COSV60592626; called by muse, mutect2, varscan2
- PRPF40B | c.1957G>A p.V653I (on ENST00000380281; = p.V640I on NM_012272.3) | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.109); catalogued as COSV53306940; called by muse, mutect2, varscan2
- PTP4A3 | c.503_508del p.T168_C170delinsS (on ENST00000329397; = p.T143_C145delinsS on NM_007079.3) | In Frame Del (DEL) | VAF 35/59 reads (59%) | catalogued as COSV61472727; called by mutect2, pindel, varscan2
- PXDN | c.1499A>G p.Y500C | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53245040; called by muse, mutect2, varscan2
- PZP | c.1045G>A p.V349M | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.814); catalogued as rs141046682; called by muse, mutect2, varscan2
- RMI1 | c.1759G>C p.D587H | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57937710; called by muse, mutect2, varscan2
- SAFB | c.1862+1G>T p.X621_splice | Splice Site (SNP) | VAF 10/103 reads (10%) | catalogued as COSV52653656; called by muse, mutect2, varscan2
- SH3PXD2B | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.197); catalogued as COSV61129715; called by muse, mutect2, varscan2
- SLC6A3 | c.33G>A p.M11I | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV54368874; called by muse, mutect2, varscan2
- SLFN12 | c.503G>A p.C168Y | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV59227452; called by muse, mutect2, varscan2
- SNX9 | c.99G>A p.P33= | Splice Region (SNP) | VAF 71/188 reads (38%) | catalogued as rs145589455; called by muse, mutect2, varscan2
- SPAG6 | c.1033T>C p.S345P | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.356); catalogued as COSV57623523; called by muse, mutect2, varscan2
- SRPRA | c.842T>A p.I281N | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.018); catalogued as COSV55008745; called by muse, mutect2, varscan2
- TAS2R14 | c.658G>A p.G220R | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs773473266, COSV67862023; called by muse, mutect2, varscan2
- TMX3 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.696); catalogued as COSV55187447; called by muse, mutect2, varscan2
- UBE4B | c.3101C>T p.T1034M (on ENST00000343090 / NM_001105562.3; = p.T905M on NM_006048.5) | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV53541143; called by muse, mutect2, varscan2
- WDR70 | c.602G>A p.G201E | Missense Mutation (SNP) | VAF 101/338 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54282208; called by muse, mutect2, varscan2
- WSCD1 | c.1423G>A p.V475I | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.644); catalogued as rs191802540; called by muse, mutect2, varscan2
- XKR9 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 40/187 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs200806311, COSV68772526; called by muse, mutect2, varscan2
- ZC3H12A | c.1348C>T p.L450F | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.521); catalogued as COSV66104502; called by muse, mutect2, varscan2
- ZDHHC9 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 48/58 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs754241413, COSV64097347; called by muse, mutect2, varscan2
- ZNF33A | c.1720C>T p.H574Y (on ENST00000458705 / NM_006974.3; = p.H575Y on NM_006954.2) | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56727446; called by muse, mutect2, varscan2
- ZNF385B | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs753184978, COSV61176049; called by muse, mutect2, varscan2
- B2M | c.43_44del p.L15Ffs*41 | Frame Shift Del (DEL) | VAF 16/32 reads (50%) | called by pindel, varscan2
- DPP8 | c.1061G>A p.G354E (on ENST00000341861 / NM_001320875.2; = p.G338E on NM_017743.6) | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.733); called by muse, mutect2
- FKBP4 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- GC | c.910dup p.T304Nfs*33 | Frame Shift Ins (INS) | VAF 11/88 reads (13%) | called by mutect2, pindel, varscan2
- KCTD4 | c.79G>T p.G27* | Nonsense Mutation (SNP) | VAF 30/956 reads (3%) | called by muse, mutect2
- MED13 | c.3818_3863del p.Q1273Lfs*12 | Frame Shift Del (DEL) | VAF 18/123 reads (15%) | called by mutect2, pindel
- PARN | c.222del p.F74Lfs*11 | Frame Shift Del (DEL) | VAF 33/81 reads (41%) | called by mutect2, pindel, varscan2
- SBNO1 | c.2777_2779del p.Q926del (on ENST00000420886; = p.Q925del on NM_018183.5) | In Frame Del (DEL) | VAF 34/104 reads (33%) | called by pindel, varscan2
- UBE2NL | c.341A>T p.N114I | Missense Mutation (SNP) | VAF 111/139 reads (80%) | SIFT deleterious (0.02); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- YBX3 | c.947C>G p.A316G | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2
- ADAMTS16 | c.3096C>T p.S1032= | Silent (SNP) | VAF 52/88 reads (59%) | catalogued as rs1392111856, COSV56986282; called by muse, mutect2
- AUTS2 | c.3312C>G p.L1104= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV61426730; called by muse, mutect2, varscan2
- CAPRIN2 | c.3009G>A p.K1003= | Silent (SNP) | VAF 37/96 reads (39%) | catalogued as COSV51835079; called by muse, mutect2, varscan2
- DGKG | c.462G>A p.S154= | Silent (SNP) | VAF 34/83 reads (41%) | catalogued as rs758220917, COSV53967612; called by muse, mutect2, varscan2
- DOCK4 | c.333C>A p.L111= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV70315179, COSV70325787; called by muse, mutect2, varscan2
- ENAM | c.504C>T p.P168= | Silent (SNP) | VAF 29/82 reads (35%) | catalogued as rs1459527928, COSV68536843; called by muse, mutect2, varscan2
- IDO2 | c.297A>G p.G99= (on ENST00000389060; = p.G112= on NM_194294.2) | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV58428731; called by muse, mutect2, varscan2
- LGALS3BP | c.975G>A p.V325= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV53165960; called by muse, mutect2, varscan2
- NMNAT2 | c.843C>T p.D281= | Silent (SNP) | VAF 28/99 reads (28%) | catalogued as rs150203304, COSV54271476; called by muse, mutect2, varscan2
- OR2G6 | c.726G>A p.S242= | Silent (SNP) | VAF 44/101 reads (44%) | catalogued as rs552819557, COSV58573606, COSV58575678; called by muse, mutect2, varscan2
- SHANK1 | c.2787G>A p.P929= | Silent (SNP) | VAF 10/14 reads (71%) | catalogued as rs746014607, COSV53253292, COSV53260616; called by muse, mutect2, varscan2
- SHE | c.675C>T p.N225= | Silent (SNP) | VAF 46/96 reads (48%) | catalogued as rs1192211696, COSV59072226; called by muse, mutect2, varscan2
- SLC6A2 | c.468C>T p.I156= | Silent (SNP) | VAF 44/126 reads (35%) | catalogued as rs769118691, COSV54922552; called by muse, mutect2, varscan2
- TENM3 | c.6291G>A p.S2097= | Silent (SNP) | VAF 51/150 reads (34%) | catalogued as rs776630968, COSV69317553; called by muse, mutect2, varscan2
- TUBA1B | c.1158G>A p.E386= | Silent (SNP) | VAF 33/109 reads (30%) | catalogued as COSV60138316; called by muse, mutect2, varscan2
- KRT18P55 | n.791G>A | RNA (SNP) | VAF 14/34 reads (41%) | catalogued as rs774134668; called by muse, varscan2
